Somatic mutation profile of tumor specimen ALCH-AE0N-TTP1-A (aliquot ALCH-AE0N-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE0N, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.0 years (29,235 days).
Specimen ALCH-AE0N-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d4baf35c-97cb-4df2-8299-1ec4f575a18c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0N-NB1-A (Blood Derived Normal), aliquot ALCH-AE0N-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ef7c4e9-7319-4edf-b619-81cca82e449b

The open-access MAF lists 217 somatic variants for this specimen: 148 protein-altering or splice-affecting, 37 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 37, Intron 15, RNA 9, Frame Shift Ins 6, Nonsense Mutation 4, 5'UTR 3, Frame Shift Del 3, 3'UTR 3, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 228/770 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2819C>T p.T940M | Missense Mutation (SNP) | VAF 47/368 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM082461, COSV66070418; called by muse, mutect2, varscan2
- ADCY2 | c.2306C>A p.A769D | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV57897081; called by muse, mutect2
- ADCY8 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 46/344 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs983062571, COSV53910492; called by muse, mutect2
- AFM | c.251del p.P84Qfs*76 | Frame Shift Del (DEL) | VAF 19/182 reads (10%) | catalogued as rs1366806464; called by mutect2, pindel, varscan2
- ATM | c.7342G>A p.D2448N | Missense Mutation (SNP) | VAF 127/644 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53724608, COSV53729065, COSV53776376; called by muse, mutect2, varscan2
- CDH7 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 36/474 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100542619; called by muse, mutect2
- CHST1 | c.1019C>A p.P340H | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1286733851, COSV100346583; called by muse, mutect2, varscan2
- CNTNAP2 | c.1643G>A p.S548N | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as COSV62182846; called by muse, mutect2
- COL25A1 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs1196817524; called by muse, mutect2
- CRAMP1 | c.2965G>A p.V989M | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1272377755; called by muse, mutect2, varscan2
- CSMD3 | c.6137C>A p.A2046E (on ENST00000297405 / NM_001363185.1; = p.A1942E on NM_052900.3) | Missense Mutation (SNP) | VAF 92/680 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52209181; called by muse, mutect2, varscan2
- CSMD3 | c.4710G>T p.Q1570H (on ENST00000297405 / NM_001363185.1; = p.Q1466H on NM_052900.3) | Missense Mutation (SNP) | VAF 95/587 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV52298115; called by muse, mutect2, varscan2
- DIS3 | c.1739G>T p.S580I | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66708335; called by muse, mutect2, varscan2
- DTNB | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 60/357 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs377592272; called by muse, mutect2, varscan2
- EEPD1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 109/651 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.189); catalogued as COSV54197068, COSV54198786; called by muse, mutect2, varscan2
- FLNC | c.2845G>C p.D949H | Missense Mutation (SNP) | VAF 93/476 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs761905908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GASK1A | c.1006C>A p.R336S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56183171; called by muse, mutect2, varscan2
- GRIN3A | c.1954A>T p.S652C | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62451075; called by muse, mutect2
- HCK | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs746368765, COSV52946521; called by muse, mutect2
- HDAC9 | c.3178G>A p.G1060S (on ENST00000441542 / NM_178425.3; = p.G1057S on NM_178423.3) | Missense Mutation (SNP) | VAF 34/286 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.168); catalogued as COSV101286721, COSV67770854, COSV67787716; called by muse, mutect2, varscan2
- HIF3A | c.1325G>T p.S442I (on ENST00000377670 / NM_152795.4; = p.S373I on NM_022462.4) | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs764281133; called by muse, mutect2, varscan2
- IGKV5-2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 72/732 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs758563319; called by muse, mutect2
- INPP5B | c.1502G>A p.R501Q (on ENST00000373023; = p.R421Q on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/206 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202221695, COSV65960127; called by muse, mutect2, varscan2
- LGALS9 | c.782G>T p.G261V (on ENST00000395473 / NM_009587.3; = p.G229V on NM_002308.4) | Missense Mutation (SNP) | VAF 83/394 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119461; called by muse, mutect2, varscan2
- LINGO2 | c.286G>T p.V96L | Missense Mutation (SNP) | VAF 48/460 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as COSV100430518, COSV99060957; called by muse, mutect2
- NPAS3 | c.1613A>G p.E538G (on ENST00000356141 / NM_001164749.2; = p.E506G on NM_022123.3) | Missense Mutation (SNP) | VAF 34/564 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as rs1388266219; called by muse, mutect2
- OLFM4 | c.97G>T p.G33C | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.087); catalogued as COSV99524634; called by muse, mutect2, varscan2
- OR10A2 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs201352225; called by muse, mutect2, varscan2
- OR14C36 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV58601122; called by muse, mutect2
- OR2D2 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 65/473 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV55057555, COSV55057833; called by muse, mutect2, varscan2
- OR8B12 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.35); catalogued as rs368885076; called by muse, mutect2, varscan2
- OR8H3 | c.889G>T p.V297L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV57910966; called by muse, mutect2
- OTUD1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.154); catalogued as rs927974791; called by muse, mutect2, varscan2
- OXCT2 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV59594184; called by muse, mutect2, varscan2
- PCDHA4 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 89/398 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1554124008; called by muse, mutect2, varscan2
- PCDHA4 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 89/402 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63538827; called by muse, mutect2, varscan2
- PDE10A | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 32/245 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370604056; called by muse, mutect2, varscan2
- PTCRA | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 152/663 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV58977023; called by mutect2, varscan2
- PTOV1 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1459268287; called by muse, mutect2
- RORB | c.1231C>A p.H411N (on ENST00000396204 / NM_001365023.1; = p.H400N on NM_006914.4) | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as COSV65334113; called by muse, mutect2, varscan2
- SLC2A9 | c.1493T>C p.V498A | Missense Mutation (SNP) | VAF 146/907 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1226431051; called by muse, mutect2, varscan2
- SLC30A5 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 79/553 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.027); catalogued as rs1436718164; called by muse, mutect2, varscan2
- SLC30A9 | c.111G>C p.E37D | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.019); catalogued as COSV52553632; called by muse, varscan2
- STMN4 | c.109G>T p.A37S (on ENST00000265770 / NM_001283054.2; = p.G37C on NM_030795.4) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as COSV99740799; called by muse, mutect2, varscan2
- TENT5D | c.392T>A p.V131E | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57635449; called by muse, mutect2
- USP24 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs555962143, COSV99601333; called by muse, mutect2, varscan2
- ZNF676 | c.1103C>A p.P368H (on ENST00000650058; = p.P336H on NM_001001411.3) | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs767344565, COSV68094686; called by muse, mutect2
- ABCB1 | c.1526C>T p.A509V | Missense Mutation (SNP) | VAF 146/802 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ABCB11 | c.2687T>A p.F896Y | Missense Mutation (SNP) | VAF 36/460 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.92); called by muse, mutect2
- ABCB5 | c.2744C>A p.A915E (on ENST00000404938 / NM_001163941.2; = p.A470E on NM_178559.6) | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ABCD3 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 58/710 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.034); called by muse, mutect2
- AC004593.2 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.1163A>T p.N388I | Missense Mutation (SNP) | VAF 46/342 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.107); called by muse, mutect2
- ADGRD2 | c.2693T>A p.L898Q | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APBB2 | c.79A>T p.T27S | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP17 | c.1741G>T p.D581Y (on ENST00000289968 / NM_001006634.3; = p.D503Y on NM_018054.6) | Missense Mutation (SNP) | VAF 60/683 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- ARHGEF18 | c.37A>T p.S13C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASH1L | c.7120A>C p.I2374L (on ENST00000368346 / NM_001366177.2; = p.I2369L on NM_018489.3) | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ASTN1 | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 33/439 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 22/194 reads (11%) | called by mutect2, varscan2
- BBS10 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 48/536 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- BBS10 | c.757G>T p.G253C | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- BTBD11 | c.1171A>T p.R391* | Nonsense Mutation (SNP) | VAF 42/180 reads (23%) | called by muse, varscan2
- CADM2 | c.406G>T p.V136F (on ENST00000407528 / NM_001167674.2; = p.V138F on NM_153184.4) | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CDH22 | c.1733C>A p.P578H | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDH23 | c.9424C>A p.L3142M | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH9 | c.1763T>A p.V588E | Missense Mutation (SNP) | VAF 137/928 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CENPE | c.5275G>A p.E1759K | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.135); called by muse, varscan2
- CSMD3 | c.5326C>A p.P1776T (on ENST00000297405 / NM_001363185.1; = p.P1672T on NM_052900.3) | Missense Mutation (SNP) | VAF 140/824 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- CSNK1D | c.719_721del p.L240del | In Frame Del (DEL) | VAF 79/628 reads (13%) | called by pindel, varscan2
- DLGAP3 | c.2167C>A p.P723T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); called by muse, mutect2
- DNAH9 | c.3124G>T p.D1042Y | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC10 | c.470G>T p.G157V | Missense Mutation (SNP) | VAF 66/618 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- EIF3H | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 99/625 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- EPYC | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 42/593 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.416); called by muse, mutect2
- FBN2 | c.8250G>T p.E2750D | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRAS1 | c.5907G>C p.Q1969H | Missense Mutation (SNP) | VAF 74/394 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FUT5 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABBR2 | c.871del p.E291Sfs*32 | Frame Shift Del (DEL) | VAF 55/592 reads (9%) | called by mutect2, pindel
- HECTD4 | c.6133G>A p.G2045S | Missense Mutation (SNP) | VAF 58/648 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (1); called by muse, mutect2
- HORMAD1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGLL1 | c.570_571insT p.S191* | Frame Shift Ins (INS) | VAF 50/401 reads (12%) | called by mutect2, pindel, varscan2
- ISX | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA8 | c.395C>A p.S132Y | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ITPKA | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPR2 | c.5869C>G p.Q1957E | Missense Mutation (SNP) | VAF 86/653 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNS2 | c.731C>T p.A244V | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KIAA1109 | c.6192dup p.V2065Cfs*13 | Frame Shift Ins (INS) | VAF 37/199 reads (19%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.4088A>T p.H1363L | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KMT2C | c.10619C>G p.S3540C | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LATS1 | c.2330A>G p.N777S | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- LMAN1 | c.1320A>T p.K440N | Missense Mutation (SNP) | VAF 56/572 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- LRP1B | c.3116dup p.I1040Dfs*5 | Frame Shift Ins (INS) | VAF 22/148 reads (15%) | called by mutect2, pindel
- LRRC30 | c.497G>A p.R166K | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- LRRC7 | c.2415C>A p.N805K (on ENST00000651989 / NM_001370785.2; = p.N772K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/310 reads (9%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- LRRTM1 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 53/363 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- METTL21C | c.703G>C p.D235H | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MMP16 | c.1007C>A p.P336H | Missense Mutation (SNP) | VAF 102/633 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MN1 | c.2200G>T p.D734Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MPP7 | c.1618G>T p.D540Y | Missense Mutation (SNP) | VAF 61/410 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MSH3 | c.541G>C p.V181L | Missense Mutation (SNP) | VAF 65/378 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MT1B | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 25/286 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYH1 | c.4063C>A p.Q1355K | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- MYH3 | c.171T>A p.D57E | Missense Mutation (SNP) | VAF 107/463 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYO18B | c.5593C>G p.H1865D | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- NCAPH | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NKX1-2 | c.527T>A p.V176E | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NOTCH2 | c.4004dup p.F1337Ifs*16 | Frame Shift Ins (INS) | VAF 69/769 reads (9%) | called by mutect2, pindel
- NPAS1 | c.446T>C p.F149S | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN3 | c.2670C>A p.Y890* (on ENST00000335750 / NM_001330195.2; = p.Y517* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 38/342 reads (11%) | called by muse, mutect2, varscan2
- NTS | c.179A>C p.N60T | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- OR2T8 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 50/594 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- OR6Y1 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHGA4 | c.1764C>G p.D588E | Missense Mutation (SNP) | VAF 57/293 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.5638G>T p.V1880L | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2
- PEG3 | c.3935G>T p.G1312V | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PIEZO2 | c.6491C>A p.T2164K | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PIGR | c.534C>A p.D178E | Missense Mutation (SNP) | VAF 268/808 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIP4K2B | c.11A>T p.N4I | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PLTP | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXNA4 | c.5416dup p.S1806Kfs*30 | Frame Shift Ins (INS) | VAF 52/279 reads (19%) | called by mutect2, pindel, varscan2
- PRDM16 | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- PRL | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 44/193 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PROKR2 | c.606C>A p.S202R | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2
- PTPRC | c.3041C>T p.P1014L | Missense Mutation (SNP) | VAF 80/950 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- RBM42 | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RNASE10 | c.273dup p.G92Wfs*3 | Frame Shift Ins (INS) | VAF 40/353 reads (11%) | called by pindel, varscan2
- RP1L1 | c.6627A>T p.L2209F | Missense Mutation (SNP) | VAF 42/375 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SHOC1 | c.3929T>A p.L1310* | Nonsense Mutation (SNP) | VAF 32/280 reads (11%) | called by muse, mutect2, varscan2
- SLC9A3 | c.307G>C p.D103H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SNRNP70 | c.1190G>C p.G397A | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SPON1 | c.577G>T p.D193Y | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- STYXL2 | c.2785A>G p.K929E | Missense Mutation (SNP) | VAF 67/351 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SUN5 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 69/387 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- SYT3 | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TAS1R1 | c.1152T>A p.S384R | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- TBX4 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 131/757 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNR | c.1601T>G p.I534S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRUB2 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWF | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- YEATS2 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ZAN | c.415G>T p.G139C | Missense Mutation (SNP) | VAF 48/444 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZDHHC22 | c.668T>C p.V223A | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF142 | c.602T>C p.V201A | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF469 | c.10801G>T p.A3601S (on ENST00000437464; = p.A3629S on NM_001367624.2) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF543 | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- ZNF598 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AXIN2 | c.30C>T p.L10= | Silent (SNP) | VAF 117/344 reads (34%) | called by muse, mutect2, varscan2
- C12orf4 | c.1416C>T p.L472= | Silent (SNP) | VAF 86/536 reads (16%) | called by muse, mutect2, varscan2
- CACNB2 | c.1827C>T p.S609= (on ENST00000324631 / NM_201596.3; = p.S554= on NM_000724.4) | Silent (SNP) | VAF 28/264 reads (11%) | catalogued as rs542191650; called by muse, mutect2
- CADM2 | c.600G>T p.A200= (on ENST00000407528 / NM_001167674.2; = p.A202= on NM_153184.4) | Silent (SNP) | VAF 48/507 reads (9%) | catalogued as COSV67357754; called by muse, mutect2
- CCDC88C | c.3546G>A p.S1182= | Silent (SNP) | VAF 44/235 reads (19%) | catalogued as rs771345343, COSV66237273; called by muse, mutect2, varscan2
- CD163L1 | c.1761C>T p.G587= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs926502193, COSV58011231; called by muse, mutect2
- CHST1 | c.1020C>A p.P340= | Silent (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- DPEP2 | c.177T>C p.A59= | Silent (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
- EIF3H | c.669T>G p.A223= | Silent (SNP) | VAF 109/718 reads (15%) | called by muse, mutect2, varscan2
- FAM216A | c.294G>A p.A98= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs778350925, COSV66601005; called by muse, mutect2, varscan2
- FAM71E2 | c.402C>A p.A134= | Silent (SNP) | VAF 10/132 reads (8%) | called by muse, mutect2
- FGF23 | c.612C>T p.A204= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs374830674, COSV99426248; called by muse, varscan2
- GALR1 | c.507C>A p.P169= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- GPR37 | c.789G>T p.A263= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV58256104; called by muse, varscan2
- HMBOX1 | c.264T>G p.A88= | Silent (SNP) | VAF 28/358 reads (8%) | called by muse, mutect2
- MUC16 | c.29148G>A p.T9716= | Silent (SNP) | VAF 38/179 reads (21%) | catalogued as rs758632603; called by muse, mutect2, varscan2
- NAT10 | c.2952G>T p.S984= | Silent (SNP) | VAF 48/281 reads (17%) | catalogued as rs747148208; called by muse, mutect2, varscan2
- NAV3 | c.3850C>A p.R1284= | Silent (SNP) | VAF 82/779 reads (11%) | catalogued as COSV99889205; called by muse, mutect2, varscan2
- NOTCH3 | c.4200C>G p.R1400= | Silent (SNP) | VAF 17/88 reads (19%) | called by muse, mutect2, varscan2
- NR0B1 | c.669G>A p.A223= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs1311357786; called by muse, mutect2, varscan2
- NRXN2 | c.3909C>T p.G1303= | Silent (SNP) | VAF 30/150 reads (20%) | called by muse, mutect2, varscan2
- OR10A2 | c.735C>A p.T245= | Silent (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- OR14C36 | c.606G>T p.L202= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as COSV58602014; called by muse, mutect2
- OR2B11 | c.186C>A p.P62= | Silent (SNP) | VAF 42/324 reads (13%) | catalogued as COSV59509548, COSV59510563; called by muse, mutect2, varscan2
- OR51I2 | c.135C>A p.I45= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV58298957; called by muse, mutect2, varscan2
- P2RY2 | c.1002C>T p.R334= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.2220C>T p.D740= | Silent (SNP) | VAF 30/135 reads (22%) | called by muse, mutect2, varscan2
- R3HCC1 | c.267G>T p.R89= (on ENST00000411463; = p.R49= on NM_001136108.3) | Silent (SNP) | VAF 33/227 reads (15%) | called by muse, mutect2, varscan2
- SHROOM3 | c.5856G>T p.L1952= | Silent (SNP) | VAF 92/536 reads (17%) | called by muse, mutect2, varscan2
- SLIT2 | c.3162C>A p.I1054= | Silent (SNP) | VAF 34/476 reads (7%) | called by muse, mutect2
- SSU72P8 | c.402G>T p.V134= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- SYT3 | c.1488C>A p.P496= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- TLR4 | c.1644T>A p.V548= (on ENST00000355622 / NM_138554.5; = p.V508= on NM_003266.4) | Silent (SNP) | VAF 52/506 reads (10%) | called by muse, mutect2
- TPP1 | c.858C>T p.N286= | Silent (SNP) | VAF 85/492 reads (17%) | catalogued as rs1420315178; called by muse, mutect2, varscan2
- USO1 | c.2761C>T p.L921= | Silent (SNP) | VAF 44/340 reads (13%) | catalogued as COSV53710126; called by muse, mutect2, varscan2
- WDR88 | c.441T>C p.P147= | Silent (SNP) | VAF 62/408 reads (15%) | called by muse, mutect2, varscan2
- WNK4 | c.822G>A p.P274= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1188977888, COSV53820727; called by muse, mutect2
- AC044798.1 | n.240C>A | RNA (SNP) | VAF 17/277 reads (6%) | called by muse, mutect2
- AC142381.4 | n.499+32227C>T | Intron (SNP) | VAF 44/235 reads (19%) | catalogued as rs768982930; called by muse, mutect2, varscan2
- ADAM6 | n.993G>A | RNA (SNP) | VAF 28/286 reads (10%) | catalogued as rs1308283451; called by muse, mutect2
- AL033381.1 | n.397A>T | RNA (SNP) | VAF 85/389 reads (22%) | called by muse, mutect2, varscan2
- ALAS1 | c.-13A>G | 5'UTR (SNP) | VAF 45/201 reads (22%) | catalogued as rs776120817; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501466 del T | 5'Flank (DEL) | VAF 39/263 reads (15%) | called by mutect2, pindel, varscan2
- CD200R1L | c.46+4393T>A | Intron (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- CDC14A | chr1:100351750 G>A | 5'Flank (SNP) | VAF 30/291 reads (10%) | called by muse, mutect2, varscan2
- CES5A | c.-14C>A | 5'UTR (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- CFLAR | c.1305-826G>T | Intron (SNP) | VAF 35/281 reads (12%) | called by muse, mutect2, varscan2
- CFLAR | c.1305-825G>T | Intron (SNP) | VAF 36/283 reads (13%) | called by muse, mutect2, varscan2
- CUX2 | c.63+65769C>T | Intron (SNP) | VAF 21/285 reads (7%) | catalogued as rs952542333; called by muse, mutect2
- ETV2 | c.71-40G>C | Intron (SNP) | VAF 42/259 reads (16%) | called by muse, mutect2, varscan2
- HDAC6 | c.*357T>A | 3'UTR (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.359A>G | RNA (SNP) | VAF 52/624 reads (8%) | catalogued as rs771214065; called by muse, mutect2
- LRP1B | c.13247+949A>T | Intron (SNP) | VAF 16/346 reads (5%) | catalogued as COSV67252917; called by muse, mutect2
- MAGI2 | c.538+43652T>C | Intron (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- MYH6 | c.1581+35T>C | Intron (SNP) | VAF 61/260 reads (23%) | called by muse, mutect2, varscan2
- NPIPB1P | n.699G>T | RNA (SNP) | VAF 100/1039 reads (10%) | called by muse, mutect2
- PKP2 | c.2490-48G>A | Intron (SNP) | VAF 31/365 reads (8%) | called by muse, mutect2
- PLEKHA8P1 | n.909G>T | RNA (SNP) | VAF 53/297 reads (18%) | called by muse, mutect2, varscan2
- RNF5P1 | n.67G>T | RNA (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- RRH | c.107-20A>G | Intron (SNP) | VAF 36/402 reads (9%) | catalogued as rs754813908; called by muse, mutect2
- RTL8A | c.*393C>G | 3'UTR (SNP) | VAF 92/263 reads (35%) | called by muse, mutect2, varscan2
- SMCO2 | c.601-13G>T | Intron (SNP) | VAF 53/204 reads (26%) | called by muse, mutect2, varscan2
- TBC1D3P2 | n.106G>T | RNA (SNP) | VAF 147/779 reads (19%) | called by muse, mutect2, varscan2
- TMEM135 | c.*5814G>A | 3'UTR (SNP) | VAF 89/993 reads (9%) | catalogued as rs1250780303; called by muse, mutect2
- TUBA3C | c.-47T>A | 5'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs773471568; called by muse, mutect2, varscan2
- VPS8 | c.1782-1408G>C | Intron (SNP) | VAF 12/294 reads (4%) | catalogued as rs1260580351; called by muse, mutect2
- XKR6 | c.764+62902G>T | Intron (SNP) | VAF 38/372 reads (10%) | called by muse, mutect2
- Z85994.1 | n.218C>G | RNA (SNP) | VAF 57/296 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1221C>T | Intron (SNP) | VAF 19/305 reads (6%) | called by muse, mutect2
